Gene-level copy-number profile of tumor specimen C3N-03233-03 from CPTAC case C3N-03233, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.2 years (24,895 days).
Specimen C3N-03233-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0b199363-4f92-4267-900d-1a28aceea4a0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03233-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/b1c189ef-e816-44d1-854b-939885f3d359

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1; copy number 2: 8,620; copy number 3: 2,756; copy number 4: 32,835; copy number 5: 5,103; copy number 6: 4,009; copy number 7: 1,881; copy number 8: 2,320; copy number 9: 769; copy number 10: 591; copy number 17: 26.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:183,705,931–183,706,031, 1 gene (within-gene range 0–4): RNU6-1053P.
- chr21:32,841,496–32,841,995, 2 genes (within-gene range 0–3): AP000281.1, SNORA70.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,386 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,461,221–166,481,565, 910 genes, copy number 9–17 (within-gene range 8–17) (broad region; genes not listed).
- chr1:173,351,689–174,160,165, 26 genes, copy number 9 (within-gene range 8–9): AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT.
- chr4:19,098,199–20,037,972, 8 genes, copy number 9: AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1.
- chr4:20,728,606–21,948,772, 1 gene, copy number 9 (within-gene range 6–9): KCNIP4.
- chr4:21,304,468–25,201,440, 33 genes, copy number 9 (within-gene range 7–9): AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6, AC097512.1, AC092440.1, RFPL4AP3, AC093607.1, ERVH-1, PPARGC1A, AC092834.1, DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473, AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2, SEPSECS, SEPSECS-AS1.
- chr5:58,198–26,749,997, 408 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
